Somatic mutation profile of tumor specimen C3L-08313-05 (aliquot CPT0503360006) from CPTAC case C3L-08313, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.3 years (26,053 days).
Specimen C3L-08313-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8295d9c7-a494-408c-9266-34844d320bfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08313-31 (Blood Derived Normal), aliquot CPT0503470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d41f2ab-cd49-467d-8713-5354fbd85994

The open-access MAF lists 196 somatic variants for this specimen: 126 protein-altering or splice-affecting, 61 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 61, Intron 8, Nonsense Mutation 4, Splice Region 4, Frame Shift Ins 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCK | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1085307455, CM001170, COSV60785720; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 85/269 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC127029.3 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as rs377027593; called by muse, mutect2
- ADAMTS2 | c.1900T>G p.F634V | Missense Mutation (SNP) | VAF 72/580 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as COSV52381559; called by muse, mutect2, varscan2
- ADGRF3 | c.3110G>A p.R1037H (on ENST00000311519 / NM_001145168.1; = p.R838H on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/457 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs754971811; called by muse, mutect2, varscan2
- AGBL5 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201033068; called by muse, varscan2
- AKAP6 | c.6917T>G p.L2306R | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs529053250, COSV55213755; called by muse, mutect2, varscan2
- ANHX | c.504G>C p.E168D | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.652); catalogued as COSV104434909; called by muse, mutect2, varscan2
- APBA2 | c.901A>G p.K301E | Missense Mutation (SNP) | VAF 147/620 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.872); catalogued as rs1442717721; called by muse, mutect2, varscan2
- APOB | c.11379A>C p.E3793D | Missense Mutation (SNP) | VAF 91/440 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV51933058; called by muse, mutect2, varscan2
- ARL14EPL | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 38/371 reads (10%) | catalogued as rs981988957, COSV59948454, COSV59948566; called by muse, mutect2, varscan2
- BRPF3 | c.3581G>A p.R1194Q | Missense Mutation (SNP) | VAF 87/374 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs1374767860; called by muse, mutect2, varscan2
- CDH12 | c.2352A>C p.E784D | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.245); catalogued as COSV66394408; called by muse, mutect2, varscan2
- CELSR2 | c.6124C>T p.R2042W | Missense Mutation (SNP) | VAF 45/345 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs756134624, COSV54772279; called by muse, mutect2
- CYP26B1 | c.1466A>G p.K489R | Missense Mutation (SNP) | VAF 110/456 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV99071224; called by muse, mutect2, varscan2
- DDX19A | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 106/333 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1191585978; called by muse, varscan2
- DNAH1 | c.7057G>A p.V2353I | Missense Mutation (SNP) | VAF 54/376 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs781124690; called by muse, varscan2
- DTX4 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 62/466 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs750700854; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 114/416 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs755011871, COSV62569243; called by muse, mutect2, varscan2
- GOLGB1 | c.5092C>T p.R1698W | Missense Mutation (SNP) | VAF 39/339 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372673093; called by muse, mutect2, varscan2
- GPRC6A | c.2737A>G p.S913G | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1285587443; called by muse, mutect2
- GRM4 | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 68/445 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs369265043, COSV65212449; called by muse, mutect2, varscan2
- HOXC13 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 90/701 reads (13%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV54498790; called by mutect2, varscan2
- KIAA0753 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs769201608; called by muse, mutect2, varscan2
- L3MBTL4 | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 40/652 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV53118685; called by muse, mutect2
- LMOD3 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs370401036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMX1B | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 107/410 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs767072869, COSV62742039; called by muse, mutect2, varscan2
- LRRC66 | c.2285T>G p.I762S | Missense Mutation (SNP) | VAF 59/444 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV58632917; called by muse, mutect2, varscan2
- LRRN3 | c.701G>C p.G234A | Missense Mutation (SNP) | VAF 89/293 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57823353; called by muse, mutect2, varscan2
- MAGEC1 | c.2901A>C p.E967D | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV53568177; called by muse, mutect2, varscan2
- MXD3 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 149/663 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs377026834; called by muse, mutect2, varscan2
- NAP1L3 | c.1146A>T p.K382N | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100220489; called by muse, mutect2, varscan2
- NKX1-1 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 103/524 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs756663729; called by muse, varscan2
- NOS1 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 56/425 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1451276089, COSV57610696; called by muse, mutect2, varscan2
- NOTCH4 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 160/617 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.245); catalogued as COSV66683453; called by muse, mutect2, varscan2
- NPHP4 | c.4118G>A p.R1373Q | Missense Mutation (SNP) | VAF 84/305 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768550124, COSV65397252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRSN2 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 150/735 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs534543510; called by muse, mutect2, varscan2
- OR5AN1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 76/319 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs149354660; called by muse, mutect2, varscan2
- OR5T2 | c.904A>C p.S302R | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs867798059, COSV57588098; called by muse, mutect2, varscan2
- PCDHB16 | c.1433G>C p.R478T | Missense Mutation (SNP) | VAF 44/459 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs782443342; called by muse, mutect2, varscan2
- PITRM1 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 300/541 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs745432011; called by muse, mutect2, varscan2
- PLEKHG2 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 212/624 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1319918473; called by muse, varscan2
- POLG | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs564582352, COSV51523456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLRMT | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs775861722; called by muse, mutect2, varscan2
- PRKCQ | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 78/460 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs759199634, COSV54105585; called by muse, mutect2, varscan2
- PSAT1 | c.867C>T p.Y289= | Splice Region (SNP) | VAF 32/152 reads (21%) | catalogued as rs189310401; called by muse, mutect2, varscan2
- RYR2 | c.4487C>T p.P1496L | Missense Mutation (SNP) | VAF 72/442 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.76); catalogued as COSV100772160; called by muse, mutect2, varscan2
- SDK1 | c.5401G>A p.A1801T | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs759894038; called by muse, mutect2, varscan2
- SLC22A16 | c.750dup p.A251Cfs*52 | Frame Shift Ins (INS) | VAF 111/446 reads (25%) | catalogued as rs775791770; called by mutect2, pindel, varscan2
- SLC5A8 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV73311279; called by muse, mutect2, varscan2
- SMARCC2 | c.3617C>T p.T1206M | Missense Mutation (SNP) | VAF 119/435 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); catalogued as rs878964153; called by muse, mutect2, varscan2
- SP8 | c.974G>A p.R325H (on ENST00000361443 / NM_198956.4; = p.R343H on NM_182700.6) | Missense Mutation (SNP) | VAF 146/693 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63866845; called by muse, mutect2, varscan2
- SPECC1 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765197010, COSV54960895; called by muse, varscan2
- TCHH | c.4027C>G p.Q1343E | Missense Mutation (SNP) | VAF 110/520 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs1557809475; called by mutect2, varscan2
- TEX2 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 39/365 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV51981210; called by muse, mutect2, varscan2
- TF | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 58/423 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs762780399, COSV53919819; called by muse, mutect2
- TMEM250 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 115/424 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1391144471; called by muse, mutect2, varscan2
- TRIM27 | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 55/406 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.027); catalogued as rs1374232510; called by muse, mutect2, varscan2
- TRIM77 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs779471943, COSV101242023; called by muse, mutect2, varscan2
- TTN | c.41819T>C p.V13940A (on ENST00000591111; = p.V6516A on NM_003319.4) | Missense Mutation (SNP) | VAF 35/373 reads (9%) | PolyPhen benign (0); catalogued as rs767913696; called by muse, mutect2
- TUBB4A | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 78/495 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); catalogued as COSV51158544; called by muse, mutect2, varscan2
- TYRO3 | c.2560G>A p.G854R | Missense Mutation (SNP) | VAF 111/765 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.132); catalogued as rs776938696, COSV99777799; called by muse, mutect2, varscan2
- ACTN4 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 57/427 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- AGBL4 | c.1481T>G p.V494G | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- AGBL5 | c.1391T>G p.L464R | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AKAP8 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 77/300 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ANKRD18A | c.2529G>A p.Q843= | Splice Region (SNP) | VAF 26/118 reads (22%) | called by muse, varscan2
- ANKRD30B | c.3036G>T p.V1012= | Splice Region (SNP) | VAF 29/284 reads (10%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ASPM | c.3065A>T p.E1022V | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- AXDND1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CAST | c.1619C>T p.S540F (on ENST00000341926; = p.S623F on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFHR1 | c.865del p.Y289Ifs*2 | Frame Shift Del (DEL) | VAF 106/495 reads (21%) | called by mutect2, pindel, varscan2
- CLSTN2 | c.2531T>A p.L844H | Missense Mutation (SNP) | VAF 63/467 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CMPK2 | c.1120C>A p.L374M | Missense Mutation (SNP) | VAF 53/482 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DACT3 | c.1823C>G p.S608C | Missense Mutation (SNP) | VAF 97/415 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GABRA6 | c.544A>G p.S182G | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- HNRNPM | c.620T>C p.F207S | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- HTR1A | c.1214A>G p.K405R | Missense Mutation (SNP) | VAF 46/399 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- IGLON5 | c.181A>T p.T61S | Missense Mutation (SNP) | VAF 115/447 reads (26%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- IPO7 | c.683G>A p.W228* | Nonsense Mutation (SNP) | VAF 39/241 reads (16%) | called by muse, mutect2, varscan2
- ITGBL1 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 43/430 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- KDM6B | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 144/478 reads (30%) | called by muse, mutect2, varscan2
- KIAA1210 | c.946A>G p.I316V | Missense Mutation (SNP) | VAF 97/226 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KIAA1217 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LAMTOR4 | c.94dup p.D32Gfs*5 | Frame Shift Ins (INS) | VAF 96/453 reads (21%) | called by mutect2, pindel, varscan2
- LDLRAD4 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 61/924 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRP1B | c.4987T>G p.L1663V | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MAPK8IP3 | c.15G>C p.Q5H | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MGA | c.8701C>T p.L2901F (on ENST00000219905 / NM_001164273.1; = p.L2692F on NM_001080541.2) | Missense Mutation (SNP) | VAF 117/526 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- MYCBP2 | c.7818G>A p.M2606I (on ENST00000357337; = p.M2644I on NM_015057.5) | Missense Mutation (SNP) | VAF 39/434 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- MYT1L | c.1910A>G p.E637G | Missense Mutation (SNP) | VAF 46/476 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- NCOA5 | c.851C>A p.A284E | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.379); called by muse, mutect2
- NLRP3 | c.604A>C p.K202Q | Missense Mutation (SNP) | VAF 150/556 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.011); called by muse, mutect2
- NLRP5 | c.3077A>C p.K1026T | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); called by muse, mutect2
- NMNAT3 | c.202G>A p.A68T (on ENST00000296202 / NM_001320512.1; = p.A31T on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/461 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- NR1H3 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 55/469 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRK | c.4396G>C p.D1466H | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OASL | c.89A>C p.K30T | Missense Mutation (SNP) | VAF 104/464 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR1L1 | c.882T>A p.H294Q (on ENST00000373686; = p.H244Q on NM_001005236.3) | Missense Mutation (SNP) | VAF 110/392 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- OR2L2 | c.906A>C p.Q302H | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OR51L1 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52N1 | c.74T>G p.V25G | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- OR5H6 | c.484G>A p.V162I (on ENST00000642105; = p.V146I on NM_001005479.2) | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR8B3 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 86/363 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PARP6 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCF11 | c.507G>A p.S169= | Splice Region (SNP) | VAF 35/149 reads (23%) | called by muse, mutect2, varscan2
- PIK3R2 | c.155A>C p.Q52P | Missense Mutation (SNP) | VAF 86/677 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PRCC | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 80/667 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPA | c.563C>T p.T188I (on ENST00000337738 / NM_178001.2; = p.T153I on NM_021131.5) | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REV3L | c.4136C>T p.S1379F | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RHAG | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- RNF114 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 45/370 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- SARS1 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SIGLEC5 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 113/337 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- SIGLEC6 | c.695T>A p.L232H | Missense Mutation (SNP) | VAF 28/313 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC17A7 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 206/589 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- SLC2A7 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 47/345 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SON | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 138/483 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM132B | c.124T>G p.L42V | Missense Mutation (SNP) | VAF 47/402 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TMEM161A | c.893T>A p.F298Y | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.068); called by muse, varscan2
- TOPORS | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 37/294 reads (13%) | called by muse, mutect2, varscan2
- TOPORS | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- TTN | c.42395T>G p.F14132C (on ENST00000591111; = p.F6708C on NM_003319.4) | Missense Mutation (SNP) | VAF 48/418 reads (11%) | PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- VPS13B | c.11101G>T p.V3701L | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- ZNF558 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ACER1 | c.630T>C p.H210= | Silent (SNP) | VAF 20/194 reads (10%) | catalogued as rs1442892566, COSV56836128; called by muse, mutect2, varscan2
- ANK2 | c.438A>G p.V146= | Silent (SNP) | VAF 29/314 reads (9%) | catalogued as rs768531392; called by muse, mutect2
- APBA2 | c.112T>C p.L38= | Silent (SNP) | VAF 81/694 reads (12%) | catalogued as COSV68792507; called by muse, mutect2, varscan2
- ATP7B | c.549C>T p.A183= | Silent (SNP) | VAF 51/378 reads (13%) | catalogued as rs772619981, COSV99666466; ClinVar: likely benign; called by muse, mutect2, varscan2
- C1orf74 | c.327T>G p.L109= | Silent (SNP) | VAF 50/524 reads (10%) | called by muse, mutect2
- CARMIL2 | c.1851C>T p.S617= | Silent (SNP) | VAF 126/402 reads (31%) | called by muse, mutect2, varscan2
- CD109 | c.3180A>G p.R1060= | Silent (SNP) | VAF 38/208 reads (18%) | catalogued as rs1295169091; called by muse, mutect2, varscan2
- CEP350 | c.2913C>T p.A971= | Silent (SNP) | VAF 44/496 reads (9%) | catalogued as COSV100854264; called by muse, mutect2
- CHST12 | c.864G>A p.A288= | Silent (SNP) | VAF 82/640 reads (13%) | catalogued as rs780659495; called by muse, mutect2, varscan2
- CLDN17 | c.75C>G p.T25= | Silent (SNP) | VAF 100/389 reads (26%) | catalogued as rs751242174, COSV54523916, COSV99729399; called by muse, mutect2, varscan2
- COL23A1 | c.105G>A p.A35= | Silent (SNP) | VAF 50/588 reads (9%) | catalogued as rs565256510; called by muse, mutect2
- CRISP3 | c.243G>A p.R81= (on ENST00000371159 / NM_001368123.1; = p.R63= on NM_006061.4) | Silent (SNP) | VAF 26/262 reads (10%) | catalogued as rs148408897; called by muse, mutect2, varscan2
- CUX2 | c.2220G>T p.G740= | Silent (SNP) | VAF 106/719 reads (15%) | called by muse, mutect2, varscan2
- DNAH5 | c.4212A>G p.E1404= | Silent (SNP) | VAF 167/401 reads (42%) | called by muse, mutect2, varscan2
- DNHD1 | c.4380G>A p.V1460= | Silent (SNP) | VAF 141/485 reads (29%) | called by muse, mutect2, varscan2
- DRD5 | c.1002C>A p.P334= | Silent (SNP) | VAF 52/520 reads (10%) | called by muse, mutect2
- DST | c.4671C>G p.G1557= | Silent (SNP) | VAF 44/197 reads (22%) | called by muse, mutect2, varscan2
- EFR3B | c.951G>A p.S317= | Silent (SNP) | VAF 103/485 reads (21%) | catalogued as COSV53120806; called by muse, mutect2, varscan2
- EVI5 | c.1656C>T p.D552= | Silent (SNP) | VAF 36/291 reads (12%) | called by muse, mutect2, varscan2
- FHOD3 | c.2562C>T p.P854= (on ENST00000359247 / NM_001281739.3; = p.P871= on NM_025135.5) | Silent (SNP) | VAF 72/301 reads (24%) | called by muse, mutect2, varscan2
- GRIN2C | c.642C>T p.R214= | Silent (SNP) | VAF 163/568 reads (29%) | called by muse, mutect2, varscan2
- H2AC11 | c.84G>T p.V28= | Silent (SNP) | VAF 40/295 reads (14%) | called by muse, mutect2, varscan2
- HCN1 | c.2238T>G p.T746= | Silent (SNP) | VAF 331/890 reads (37%) | called by muse, mutect2, varscan2
- HSD3B7 | c.585C>T p.Y195= | Silent (SNP) | VAF 48/365 reads (13%) | catalogued as rs767801790, COSV52679639; called by muse, mutect2, varscan2
- INSC | c.1044G>A p.V348= | Silent (SNP) | VAF 54/473 reads (11%) | called by muse, mutect2, varscan2
- IRS2 | c.1782G>A p.S594= | Silent (SNP) | VAF 282/745 reads (38%) | catalogued as rs1464161443, COSV101019075; called by muse, varscan2
- JAKMIP1 | c.1353A>G p.S451= | Silent (SNP) | VAF 44/374 reads (12%) | called by muse, mutect2, varscan2
- JRK | c.555C>T p.N185= | Silent (SNP) | VAF 54/916 reads (6%) | catalogued as rs782747845; called by muse, mutect2
- KCNH4 | c.540C>T p.T180= | Silent (SNP) | VAF 62/360 reads (17%) | catalogued as rs778587156, COSV52920552; called by muse, mutect2, varscan2
- KRTAP13-3 | c.273T>C p.S91= | Silent (SNP) | VAF 115/417 reads (28%) | catalogued as COSV61879462, COSV61879897, COSV61880010; called by muse, mutect2, varscan2
- LPIN3 | c.678G>A p.S226= | Silent (SNP) | VAF 39/321 reads (12%) | catalogued as rs748696138; called by muse, mutect2, varscan2
- MAGEA4 | c.747A>G p.Q249= | Silent (SNP) | VAF 45/249 reads (18%) | catalogued as rs1205254338, COSV52342379; called by muse, mutect2, varscan2
- NRBP2 | c.462C>T p.C154= | Silent (SNP) | VAF 53/467 reads (11%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1644C>T p.N548= | Silent (SNP) | VAF 86/680 reads (13%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1923C>T p.D641= | Silent (SNP) | VAF 119/284 reads (42%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1485G>A p.P495= | Silent (SNP) | VAF 165/774 reads (21%) | catalogued as rs782361968; called by muse, mutect2, varscan2
- PCDHB6 | c.816G>A p.S272= | Silent (SNP) | VAF 87/376 reads (23%) | catalogued as rs1463000183, COSV50693020, COSV50728335; called by muse, mutect2, varscan2
- PDE1C | c.180T>C p.D60= | Silent (SNP) | VAF 35/388 reads (9%) | called by muse, mutect2
- PHLDB1 | c.3072C>T p.A1024= | Silent (SNP) | VAF 53/361 reads (15%) | called by muse, mutect2, varscan2
- PODXL | c.687G>A p.P229= | Silent (SNP) | VAF 24/226 reads (11%) | catalogued as rs964746451; called by muse, mutect2, varscan2
- PREX2 | c.2838T>G p.S946= | Silent (SNP) | VAF 90/400 reads (23%) | catalogued as rs1361294223, COSV55789196; called by muse, mutect2, varscan2
- RGS9BP | c.507C>T p.N169= | Silent (SNP) | VAF 206/524 reads (39%) | catalogued as rs1234960217; called by muse, varscan2
- RIMS2 | c.586T>C p.L196= | Silent (SNP) | VAF 75/443 reads (17%) | called by muse, mutect2, varscan2
- RMDN1 | c.657C>T p.A219= | Silent (SNP) | VAF 61/263 reads (23%) | catalogued as rs769024706, COSV101288485; called by muse, mutect2, varscan2
- SCMH1 | c.1938C>G p.L646= (on ENST00000326197 / NM_001031694.2; = p.L577= on NM_012236.4) | Silent (SNP) | VAF 38/342 reads (11%) | called by muse, mutect2, varscan2
- SLC6A19 | c.1521C>T p.Y507= | Silent (SNP) | VAF 143/383 reads (37%) | catalogued as rs1319482740, COSV58670814; ClinVar: likely benign; called by muse, varscan2
- SPEG | c.8100G>T p.P2700= | Silent (SNP) | VAF 56/389 reads (14%) | called by muse, varscan2
- SYNE1 | c.4527T>G p.S1509= (on ENST00000367255 / NM_182961.4; = p.S1516= on NM_033071.3) | Silent (SNP) | VAF 45/374 reads (12%) | catalogued as rs758339344; called by muse, mutect2, varscan2
- SYNE2 | c.12657G>A p.A4219= | Silent (SNP) | VAF 41/292 reads (14%) | catalogued as rs76668149; called by muse, mutect2, varscan2
- TCF15 | c.408C>T p.D136= | Silent (SNP) | VAF 75/676 reads (11%) | catalogued as rs765790218, COSV55720891; called by muse, mutect2, varscan2
- TMEM200C | c.459C>T p.F153= | Silent (SNP) | VAF 59/1002 reads (6%) | called by muse, mutect2
- TRAF7 | c.1443G>A p.P481= | Silent (SNP) | VAF 54/301 reads (18%) | catalogued as rs370665973; called by muse, mutect2, varscan2
- TSC1 | c.942G>A p.T314= | Silent (SNP) | VAF 52/309 reads (17%) | catalogued as rs144208203; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.29394A>G p.T9798= (on ENST00000591111; = p.T8871= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 113/399 reads (28%) | catalogued as COSV100636190; called by muse, mutect2, varscan2
- TUBB8B | c.1200C>T p.G400= | Silent (SNP) | VAF 48/678 reads (7%) | catalogued as rs771133240; called by muse, mutect2
- TXK | c.588G>C p.T196= | Silent (SNP) | VAF 29/244 reads (12%) | catalogued as COSV51918092, COSV99972528; called by muse, mutect2, varscan2
- USH2A | c.12585C>T p.F4195= | Silent (SNP) | VAF 51/421 reads (12%) | catalogued as rs763205825, COSV56330810, COSV56335899; ClinVar: likely benign; called by muse, varscan2
- XBP1 | c.144G>C p.P48= | Silent (SNP) | VAF 128/454 reads (28%) | called by mutect2, varscan2
- ZNF365 | c.414G>A p.S138= | Silent (SNP) | VAF 106/351 reads (30%) | catalogued as rs563726070, COSV67925358; called by muse, mutect2, varscan2
- ZNF516 | c.495C>T p.C165= | Silent (SNP) | VAF 62/438 reads (14%) | called by muse, mutect2, varscan2
- ZNF710 | c.1659G>A p.G553= | Silent (SNP) | VAF 80/304 reads (26%) | catalogued as rs1213230714; called by muse, mutect2, varscan2
- ABI3BP | c.1577-8503G>A | Intron (SNP) | VAF 37/339 reads (11%) | catalogued as rs949304072, COSV52531771; called by muse, mutect2, varscan2
- ABI3BP | c.1577-12044G>A | Intron (SNP) | VAF 34/410 reads (8%) | catalogued as rs1410406766, COSV52533908; called by muse, mutect2
- CDIN1 | c.716+37072G>A | Intron (SNP) | VAF 75/352 reads (21%) | catalogued as rs1232111226; called by muse, mutect2, varscan2
- CNTLN | c.1146+19A>C | Intron (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2
- ELAVL2 | c.-12-2782C>G | Intron (SNP) | VAF 57/318 reads (18%) | called by muse, mutect2, varscan2
- ESRRG | c.56+15840T>C | Intron (SNP) | VAF 59/291 reads (20%) | called by muse, mutect2, varscan2
- H2BP2 | chr1:143876102 C>T | 3'Flank (SNP) | VAF 68/1454 reads (5%) | called by muse, mutect2
- MYB | c.1203+1171C>T | Intron (SNP) | VAF 108/442 reads (24%) | catalogued as rs761564188; called by muse, mutect2, varscan2
- THAP4 | c.1614+20C>T | Intron (SNP) | VAF 63/529 reads (12%) | catalogued as COSV99079558; called by muse, mutect2, varscan2
